FM case AD6354 — Foundation Medicine Adult Cancer Clinical Dataset (FM-AD)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Adenomas and Adenocarcinomas; Primary site: Stomach.
https://portal.gdc.cancer.gov/cases/f29b4b0f-df7e-4421-ac01-f3b1ebfcd715

Male, 59.0 years: Adenocarcinoma, NOS (ICD-O-3 8140/3) of the stomach; metastasis biopsied or resected from the esophagus. Tumor nuclei on the sequenced sample's slide: 20% (pathologist estimate recorded by GDC). Sample type: Metastatic.
